FM case AD2461 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/b648d4d5-e5d6-4244-a01f-395ee83719d0

Male, 74.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
